Surgical pathology report (de-identified scan), TCGA case TCGA-46-6026, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-6026-01A (Primary Tumor).

[page 1 of 4]
PRIORITY: FROZEN SEC

TCGA-46-6026

SURGICAL PROCEDURES:

LUNG-LOBECTOMY, REGIONAL LYMPH

CLINICAL HISTORY

PRE-OPERATIVE DIAGNOSIS: RIGHT LOWER LOBE LESION

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "right lower lobe frozen section margins (bronchial)" and consists of a lobe of lung weighing 311 grams and measuring 18 x 14 x 5 cm. The pleural surface is pink, focally hemorrhagic and smooth with a puckered area, located in the anterior aspect measuring 2.5 cm. The main bronchus and vessel margins have been sealed with metallic staples. After removal the bronchial margin measures 0.4 cm in length and 0.6 cm in diameter. Vessels measure up to 0.3 cm in length and 0.5 cm in diameter. The pleural surface at the area of the puckering will be marked with black dye. Sectioning exhibits a firm gray mass measuring 4 x 3 x 2.5 cm which approaches to within 2.5 cm of the bronchial margin. A portion of the tumor is necrotic, soft and friable. Further sectioning of the lung is unremarkable exhibiting pink spongy air-filled tissue. Representative sections are submitted, cassettes as follows:

FROZEN SECTION DIAGNOSIS:	Bronchial margin, negative for tumor
Cassette 1	Vessel margin
Cassette 2	Tumor showing adjacent vessel
Cassettes 3 through 6	Random sections of tumor showing puckered pleura
Cassette 7	Tumor showing adjacent normal lung tissue
Cassette 8	Normal air filled lung tissue
FSP	Bronchial margin of resection, used for frozen section

[page 2 of 4]
B. The specimen is submitted fresh as "4R right lower paratracheal" and consists of multiple segments of yellow adipose tissue having an aggregate dimension of 4 x 3 x 1 cm. Sectioning exhibits six tan to grey black lymph nodes ranging from 0.5 to 1 cm. The lymph nodes are submitted intact and in toto, 6 (1).

C. The specimen is submitted fresh as "Level 7 subcarinal" and consists of six grey black lymph nodes ranging from 0.5 to 1.2 cm; submitted intact and in toto, 6 (1).

D. The specimen is submitted fresh as "posterior 10R right tracheobronchial angle" and consists of three tan to tan brown tissue fragments ranging from 0.4 to 0.9 cm; submitted, 3 (1).

FINAL DIAGNOSIS

- A. LUNG, RIGHT LOWER LOBE (LOBECTOMY):
- INVASIVE MODERATELY DIFFERENTIATED SQUAMOUS CARCINOMA (4 CM).
- TUMOR IS 2.5 CM FROM BRONCHIAL MARGIN AND EXTENDS TO 1 MM FROM AND DOES NOT INVADE THE VISCERAL PLEURA.
- TUMOR IS WELL CIRCUMSCRIBED WITH EXTENSIVE NECROSIS AND DESMOPLASTIC STROMAL REACTION.
- NON-NEOPLASTIC LUNG PARENCHYMA SHOWS MODERATE EMPHYSEMATOUS CHANGE.
- LYMPHO-VASCULAR INVASION IS NOT IDENTIFIED.
- ALL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR.
- B. LYMPH NODE, 4R, RIGHT LOWER PARATRACHEAL: ONE LYMPH NODE AND ASSOCIATED SOFT TISSUE WITH HEMORRHAGE, NEGATIVE FOR TUMOR.
- C. LYMPH NODE, LEVEL 7, SUBCARINAL: MULTIPLE FRAGMENTS OF LYMPH NODES AND ASSOCIATED SOFT TISSUE, ENTIRELY SUBMITTED, NEGATIVE FOR TUMOR.
- D. LYMPH NODE, 10R, POSTERIOR RIGHT TRACHEAOBRONCHIAL ANGLE: INFILTRATING POORLY DIFFERENTIATED SQUAMOUS CARCINOMA IN CAUTERIZED SOFT TISSUE WITH LYMPHOID COMPONENT.

PATHOLOGIC STAGE: pT2a N1 MX

[page 3 of 4]
SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: RIGHT
TUMOR SITE: RIGHT LOWER LOBE
TUMOR SIZE: 4 CM
HISTOLOGIC TYPE: SQUAMOUS
HISTOLOGIC GRADE: 2
EXTENT OF INVASION: CONFINED TO LUNG
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): UNINVOLVED
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC):
EMPHYSEMATOUS CHANGE.

MARGINS:

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 2.5 TO BRONCHIAL, 1 MM
TO PLEURAL SURFACE

VENOUS INVASION: ABSENT
ARTERIAL (LARGE VESSEL) INVASION: ABSENT

LYMPH NODE:

f,,, N1 - # INVOLVED/# EXAMINED: 1/MULTIPLE
f,,, N2 - # INVOLVED/#EXAMINED: 0/MULTIPLE
f,,, N3 - # INVOLVED/# EXAMINED: 0/1

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT2a N1 MX

ADDENDUM

Addendum #1

UPON FURTHER DISSECTION OF BRONCHIAL BRANCHES, THREE ADDITIONAL INTRALOBAR
LYMPH NODES WERE IDENTIFIED, NEGATIVE FOR TUMOR.

Source: NCI Genomic Data Commons file 17f76976-af7b-47f2-8f10-8d1384832088 (TCGA-46-6026.AD6737A0-C741-40D5-9548-34B0FC17F542.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).